Somatic mutation profile of tumor specimen TCGA-IB-A5SO-01A (aliquot TCGA-IB-A5SO-01A-11D-A32N-08) from TCGA case TCGA-IB-A5SO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,129 days).
Specimen TCGA-IB-A5SO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 501b94f1-4499-483b-8c8c-bc913dfe3c9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A5SO-10A (Blood Derived Normal), aliquot TCGA-IB-A5SO-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deeb2868-2fd0-439b-949e-17e20c4ef4fb

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 16/210 reads (8%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS15 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV100143320; called by muse, mutect2, varscan2
- ADGRG7 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 26/272 reads (10%) | catalogued as COSV99840809; called by muse, mutect2
- CELSR3 | c.9628C>T p.R3210W | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); catalogued as rs767576418, COSV99373327; called by muse, mutect2, varscan2
- CSMD2 | c.8572C>T p.R2858C | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.832); catalogued as rs931136413, COSV99589134; called by muse, mutect2, varscan2
- FAT3 | c.4460G>A p.R1487K | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs1421750495, COSV99965161; called by muse, mutect2
- MAPT | c.727C>T p.R243C (on ENST00000262410 / NM_001377265.1; = p.R168C on NM_016835.4) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs770059067, COSV99290331; called by muse, mutect2
- OSTF1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as rs760204520, COSV100653688; called by muse, mutect2
- PTPN5 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs367543224, COSV100659872; ClinVar: not provided; called by muse, mutect2
- RBM6 | c.1565T>G p.L522R | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99805195; called by muse, mutect2, varscan2
- RFTN2 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs779809181, COSV99695520; called by muse, mutect2
- RP1 | c.2723C>G p.A908G | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV99607193; called by muse, mutect2
- SPANXD | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781909487, COSV100982271, COSV65152551; called by muse, mutect2, varscan2
- STK31 | c.1119A>G p.I373M | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100669311, COSV100669873; called by muse, mutect2
- TGFBR2 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 23/304 reads (8%) | catalogued as COSV55449808, COSV99846957; called by muse, mutect2
- TWNK | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 26/334 reads (8%) | catalogued as rs776533804, COSV52968574; called by muse, mutect2
- UNC13C | c.6214G>A p.D2072N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV52861242; called by muse, mutect2, varscan2
- WLS | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 51/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99259464; called by muse, mutect2, varscan2
- DNMT3A | c.198A>G p.P66= | Silent (SNP) | VAF 19/368 reads (5%) | catalogued as COSV99261830; called by muse, mutect2
- EPS8L2 | c.1065C>T p.V355= | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as rs146372566; called by muse, mutect2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- HLCS | c.1431A>G p.T477= | Silent (SNP) | VAF 18/219 reads (8%) | catalogued as COSV100358131; called by muse, mutect2
- SEMA6D | c.2430G>A p.P810= (on ENST00000316364 / NM_153618.2; = p.P748= on NM_020858.2) | Silent (SNP) | VAF 30/496 reads (6%) | catalogued as rs144939945; called by muse, mutect2
- SORCS2 | c.2130C>T p.Y710= | Silent (SNP) | VAF 50/596 reads (8%) | catalogued as rs376351462; called by muse, mutect2
- OLFM2 | c.*2C>G | 3'UTR (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99321712; called by muse, mutect2
